Surgical pathology report (de-identified scan), TCGA case TCGA-3X-AAVA, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Alberta Health Services, specimen TCGA-3X-AAVA-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected
Time Reported
Order Number
Status

Final

Time Received
Time Transmitted
Ordering Provider
Relevant Information
Location

Copied To

Report Patient
Demographics (for
verification purposes)

Name:
Date of Birth:
Sex: F

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

A. Portal tissue at
B. Liver segment at

Clinical Information
Infectious patient: No
Immunocompromised: No

Liver mass

Diagnosis

A. Portal Tissue, Excision:
- Benign fibroadipose tissue.

B. Liver, Segmental Resection:
- Moderately-differentiated cholangiocarcinoma (see Synoptic Report).
- Tumor < 0.1 cm from hepatic resection margin.
- Background liver parenchyma with prominent chronic portal inflammation.

Reported by:

Electronically signed by:
Verified:

Synoptic Report
B: Intrahepatic Bile Ducts, Resection Macro
Specimen:
Liver
PROCEDURE:

ICD O-3
Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct C22.1
7/5/21/14

[page 2 of 3]
Wedge resection
TUMOR SIZE:
Greatest dimension: 7.3 cm
*Additional dimensions: 5.8 x 4.8 cm
TUMOR FOCALITY:
Multiple (specify location): 2 foci within segment

B: Intrahepatic Bile Ducts, Resection, Micro

HISTOLOGIC TYPE:
Cholangiocarcinoma
HISTOLOGIC GRADE:
GII: Moderately differentiated
TUMOR GROWTH PATTERN:
Mass-forming
MICROSCOPIC TUMOR EXTENSION:
Tumor confined to hepatic parenchyma
HEPATIC PARENCHYMAL MARGIN:
Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1 mm
BILE DUCT MARGIN:
Cannot be assessed
VENOUS (LARGE VESSEL) INVASION (V):
Not identified
SMALL VESSEL INVASION (L):
Not identified
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT2b: Multiple tumors, with or without vascular invasion
REGIONAL LYMPH NODES (pN):
pNX: Cannot be assessed

Gross Description

Received are specimens A to B. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and identifiers are labelled with the Surgical Number

A. Specimen is labelled "portal tissue"
A single soft grey tan irregular portion of tissue measuring 1.8 x 1.0 x 0.6 cm. This portion of tissue is bisected and submitted in toto in A1. Also submitted in the container multiple soft yellow lobulated tissue fragments measuring in aggregate 1.4 x 0.9 x 0.3 cm and totally submitted in A2.

B. The specimen is received fresh and is subsequently placed into formalin. The container is designated "liver segment" and consists of a 218.4 g segmental hepatectomy specimen measuring 11.8 x 8.4 x 5.4 cm. The capsular surface appears relatively smooth expect for two focal indurated light tan appearing areas measuring 5.4 x 4.3 cm on the anterior surface and on the posterior surface measuring 4.4 x 2.0 cm. The surgical resection margin is dyed with black ink. The specimen is serially sectioned to reveal a well circumscribed light tan lesion measuring 7.3 x 5.8 x 4.8 cm which grossly appears to extends right to the black inked surgical resection margin and also corresponds with the two indurated light tan capsular areas identified on both anterior and posterior surfaces. There is also secondary nodule measuring 1.0 x 0.9 x 0.9 cm which grossly is 0.8 cm away from the larger tumor, 2.8 cm from the black inked surgical resection margin and grossly appears to come right to the capsular surface.

Summary sections:

B1, 2 - representative sections of the larger lesion and grossly points of invasion to black inked resection margin
B3 - representative section of gross capsular surface involvement of the larger lesion on the

[page 3 of 3]
- anterior surface
- B4 - representative section of the larger lesion capsular surface involvement on the posterior surface
- B6 - representative section of the smaller lesion and the capsular surface involvement

Pathologist Comment

Comparison is made to previous liver biopsy specimen

The portal chronic inflammation is likely secondary to mass effect/reactive changes secondary to the tumor. Note is made of the negative autoantibody and viral hepatitis serology. Clinical correlation is required for a more definitive diagnosis.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file f337d274-8621-47f8-a03a-d2e3a508e5a6 (TCGA-3X-AAVA.4C9A220D-03E9-41CF-8FA9-4B7FD05A625A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).